Gene-level copy-number profile of tumor specimen TCGA-06-1802-01A from TCGA case TCGA-06-1802, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.7 years (22,537 days).
Specimen TCGA-06-1802-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.80632df8-1628-4cfc-829c-e0f26df286fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-1802-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af8b5869-b0bf-4406-99cb-741280850790

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 8,058; copy number 2: 45,539; copy number 3: 5,995; copy number 11: 142.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-1802-01A-01D-0591-01): tumor purity 0.84, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,077,104–24,592,104, 71 genes (broad region; genes not listed).
- chr9:25,579,657–26,118,408, 5 genes: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:27,948,078–28,670,286, 1 gene (within-gene range 0–1): LINGO2.
- chr9:28,539,735–28,566,733, 1 gene: AL445526.1.
- chr9:32,293,558–32,454,769, 3 genes (within-gene range 0–1): RNA5SP281, SLC25A5P8, ACO1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–60,038,586, 142 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,672. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
